Surgical pathology report (de-identified scan), TCGA case TCGA-56-8504, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8504-01A (Primary Tumor).

[page 1 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - J.) LUNG, LEFT, UPPER LOBE, PERIBRONCHIAL (N11L X 4), HILAR (N10L X 2), PULMONARY LIGAMENT (N9L), SUBCARINAL (N7), AND SUBAORTIC (N5L), LOBECTOMY WITH REGIONAL LYMPH NODE DISSECTION:

- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- 4.8 cm in maximum dimension.
- Visceral pleural invasion: PRESENT.
- MARGIN STATUS: NEGATIVE.
- EIGHTEEN LYMPH NODES, NEGATIVE FOR METASTASIS (0/18).
- A single lymph node shows a hyalinized nodule consistent with old granuloma.
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Invasive squamous cell carcinoma, poorly differentiated.

Primary tumor: pT2a (4.8 cm in maximum dimension).

Regional lymph nodes: pN0 (0/18).

Distant metastasis: Not applicable.

Pathologic stage: IB.

Lymphovascular invasion: Not identified.

Margin status: R0.

Lung Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, [REDACTED] and CAP protocol, [REDACTED]

[page 2 of 5]
Procedure:	Lobectomy.
Specimen type:	Lung, upper lobe.
Specimen laterality:	Left.
Specimen integrity:	Intact.
Tumor Features:	
Tumor site:	Left lung, upper lobe.
Tumor size:	Greatest dimension: 4.8 cm. Additional dimensions: 4 x 3.8 cm.
Tumor focality:	Unifocal.
Histologic type:	Squamous cell carcinoma.
Histologic grade:	Poorly differentiated (G3).
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Visceral pleural invasion:	Present.
Tumor extension into extra-pulmonary structures:	Not identified.
Treatment effect:	Not applicable.
Lymph Nodes:	Eighteen lymph nodes, negative for metastasis.
Margin Evaluation:	Negative (R0).
Distance to closest margin:	3.3 cm from the bronchial margin.
Bronchial margin:	Uninvolved by carcinoma.
Vascular margin:	Uninvolved by carcinoma.
Parenchymal margin:	Uninvolved by carcinoma.
Parietal pleural margin:	Not applicable.
Chest wall margin:	Not applicable.
Other margins:	Not applicable.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT2a (4.8 cm in greatest dimension).
Regional lymph nodes (pN):	pN0 (0/18 lymph nodes).
Distant metastasis (pM):	Not applicable.
Margin status (R):	R0.
Pathologic stage:	IB.
Additional pathologic findings:	Emphysematous changes. Apical bleb.
Comment:	Elastic stain, performed with adequate control, confirms the presence of visceral pleura invasion.

[page 3 of 5]
Source of Specimen:

- A. Left upper lobe lung
- B. N10L #1
- C. N10L #2
- D. N11L #1
- E. N11L #2
- F. N11L #3
- G. N11L #4
- H. N9L #1
- I. N7L #1
- J. N5L #1

Clinical History/Operative Dx:

Left lung cancer.

Intraoperative Diagnosis:

- A. FS: Left lobe of lung: Bronchial margins is negative for carcinoma. [REDACTED]
The intraoperative interpretation(s) was/were performed and rendered [REDACTED]
[REDACTED]

Gross Description:

A. Part A designated left upper lobe. Initially received in a fresh state, for frozen section analysis and Oncogenotyping studies, is a 242 gram predominantly inflated lobe of lung, 19.3 x 14.2 x 5.1 cm. Two bronchial stumps extend out to 0.5 and 0.7 cm, 1.0 and 1.5 cm in diameter each, respectively. The luminal pathways of both tracts demonstrates occlusion by hemorrhagic mucin plugs which are cleared, and the margins appear grossly free of tumor involvement. A palpable mass is noted in the mid medial aspect, creating a dimpled appearance of the anterior pleura. The remainder of the pleura demonstrates severe dark gray anthracotic pigmentation with the superior apex demonstrating a posterior protruding air filled apparent formation, 3.5 x 2.5 x 2.3 cm. The posterior and anterior pleura overlying the apparent mass is now differentially inked black and blue, respectively, and sectioning reveals a well circumscribed, dense light gray tumor mass, 4.8 x 4.0 x 3.8 cm. The mass is partially abuts the anterior surface and is within 0.2 cm of the posterior pleura. The tumor mass grossly approaches within 3.3 cm of the superior bronchial margin. Representative sections of the bronchial margins are submitted for frozen section and portions of tumor, perineoplastic, and uninvolved lung are submitted for Oncogenotyping studies. Sectioning along the lobar tracts demonstrates luminal paths grossly free of tumor involvement. The lung parenchyma is predominantly spongy light pink and tan, without additional nodularity. Representative

[REDACTED]

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

sections are submitted for microscopic evaluation.

Cassette summary: A1) bronchial margins, frozen section analysis, A2) pulmonary vascular margins trimmed and submitted, A3-A4) tumor mass, anterior pleura, four pieces, A5) tumor mass, nearest posterior pleura, two pieces, A6) tumor mass, lobar tract relationship, A7) bulk of tumor represented, A8) superior apex of lung, bleb candidate, A9) grossly uninvolved lung represented, two pieces, inferior and superior, A10) five small interlobar lymph node candidates, A11) three interlobar lymph node candidates.

B. Part B is designated . Received in formalin is a single light to darkened gray lymph node candidate, 0.7 x 0.4 x 0.3 cm. The lymph node is entirely submitted for microscopic evaluation in B1.

C. Part C is designated as . Received in formalin is a single light to darkened gray lymph node candidate, 0.4 x 0.3 x 0.3 cm. The lymph node is submitted in C1.

D. Part D is designated as . Received in formalin is a light to darkened gray anthracotic lymph node candidate, 2.3 x 1.4 x 0.7 cm. The specimen is trisected and entirely submitted for microscopic evaluation in D1.

E. Part E is designated as . Received in formalin are multiple light to darkened gray lymph node fragments, measuring in aggregate 1.6 x 1.5 x 0.3 cm. The lymph node tissue is entirely submitted for microscopic evaluation in a filter bag in E1.

F. Part F is designated as . Received in formalin are two tattered light to darkened gray lymph node fragments, 5 mm each. The tissue is entirely submitted for microscopic evaluation in F1.

G. Part G is designated as . Received in formalin is a single partially tattered light to darkened gray lymph node candidate, 0.8 x 0.6 x 0.4 cm. The specimen is bisected and submitted in G1.

H. Part H is designated . Received in formalin is a partially tattered light to darkened gray lymph node candidate, 0.8 x 0.7 x 0.3 cm and fragments upon manipulation, therefore is submitted in a filter bag in H1.

I. Part I is designated as . Received in formalin are multiple light to darkened gray lymph node fragments/candidates ranging from 0.5-0.7 cm each. All three fragments are submitted intact in I1.

J. Part J is designated . Received in formalin are a tattered fragments of light yellow fatty soft tissue and partially encased light to darkened gray lymph node tissue fragments/candidates which measure in aggregate 3.5 x 3.5 x 0.9 cm. The excess fat is trimmed, and the three large intact lymph node candidates, 0.5-0.7 cm, are submitted in J1 and the remaining lymph node pieces minus the trimmed fat are submitted in J2.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Emphysematous changes are also present, as well as an apical bleb. Seven peribronchial lymph nodes are identified, negative for metastasis. A single lymph node contains a hyalinized nodule,

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

consistent with old granuloma.

B. One anthracotic pigment laden lymph node is present, and is negative for metastasis.

C. One lymph node is present, and is negative for metastasis.

D. One lymph node is present, and is negative for metastasis.

E. One lymph node is present, and is negative for metastasis.

F. One lymph node is present, and is negative for metastasis.

G. One lymph node is present, and is negative for metastasis.

H. One lymph node is present, and is negative for metastasis.

I. One lymph node is present, and is negative for metastasis.

J. Four lymph nodes are present, negative for metastasis.

Source: NCI Genomic Data Commons file c3b4204e-550a-415d-bac6-f826876064e1 (TCGA-56-8504.BD602ED5-B728-4E7F-8022-CB7D0064C863.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).